Somatic mutation profile of tumor specimen MMRF_2639_1_BM_CD138pos (aliquot MMRF_2639_1_BM_CD138pos_T1_KHS5U_L13404) from MMRF case MMRF_2639, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.1 years (17,553 days).
Specimen MMRF_2639_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ddbd96df-d791-4cc8-a554-911b45e4e859.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2639_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2639_1_PB_WBC_C3_KHS5U_L13405; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc3365ba-9956-42c5-9216-407796669734

The open-access MAF lists 102 somatic variants for this specimen: 48 protein-altering or splice-affecting, 12 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 22, Silent 12, Intron 11, 3'Flank 4, 5'UTR 3, Splice Site 3, Nonsense Mutation 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 57/200 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66705800, COSV66705888; called by muse, mutect2, varscan2
- KRAS | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 10/47 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.884); catalogued as rs1057519725, COSV55498939; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 27/168 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACTL9 | c.1172G>A p.R391H | Missense Mutation (SNP) | VAF 61/126 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.019); catalogued as rs782182119, COSV61006158; called by muse, mutect2, varscan2
- ADAM30 | c.1802C>G p.P601R | Missense Mutation (SNP) | VAF 32/225 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.179); catalogued as COSV65561534; called by muse, mutect2, varscan2
- AMOTL1 | c.2027G>A p.R676Q | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.319); catalogued as rs770787342, COSV58567771; called by muse, mutect2, varscan2
- CARD6 | c.1780C>A p.Q594K | Missense Mutation (SNP) | VAF 141/295 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV54567172; called by muse, mutect2, varscan2
- CCDC171 | c.919C>T p.R307W | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs757715493, COSV52644789; called by muse, mutect2, varscan2
- CTNNB1 | c.157G>T p.E53* | Nonsense Mutation (SNP) | VAF 65/227 reads (29%) | catalogued as COSV62694552; called by muse, mutect2, varscan2
- FRRS1L | c.602G>A p.R201H | Missense Mutation (SNP) | VAF 39/294 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs574642289; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGHV2-70 | c.145A>G p.S49G | Missense Mutation (SNP) | VAF 60/136 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.052); catalogued as rs374002647; called by muse, varscan2
- IGLV3-1 | c.47-1G>A p.X16_splice | Splice Site (SNP) | VAF 73/135 reads (54%) | catalogued as rs773087667; called by muse, varscan2
- IGLV3-1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 73/138 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs144850905; called by muse, varscan2
- INSYN2A | c.41C>T p.S14L | Missense Mutation (SNP) | VAF 195/409 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs772004736; called by muse, mutect2, varscan2
- ITPRID1 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60070579, COSV60072018; called by muse, mutect2
- MAPK8IP3 | c.3932T>C p.M1311T | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1021260810; called by muse, mutect2, varscan2
- OR5AR1 | c.686G>A p.R229H | Missense Mutation (SNP) | VAF 26/191 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs143115322; called by muse, mutect2, varscan2
- RBP1 | c.139G>A p.G47S (on ENST00000619087 / NM_001365940.2; = p.G109S on NM_002899.5) | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.653); catalogued as rs775743096, COSV51676270; called by muse, mutect2
- RUNX1T1 | c.1576T>A p.C526S (on ENST00000265814 / NM_001198628.1; = p.C499S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56155438; called by muse, mutect2
- SCN1A | c.2959T>C p.F987L (on ENST00000303395 / NM_001202435.3; = p.F976L on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM1211352; called by muse, mutect2, varscan2
- SH3PXD2B | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.54); PolyPhen benign (0.134); catalogued as rs373756241, COSV61124475; called by muse, mutect2, varscan2
- TAL1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99595834; called by muse, mutect2, varscan2
- TRPM3 | c.3224G>A p.R1075Q (on ENST00000357533 / NM_001366142.2; = p.R930Q on NM_020952.6) | Missense Mutation (SNP) | VAF 39/72 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.348); catalogued as rs201712298; called by muse, mutect2, varscan2
- TUBGCP2 | c.28G>A p.V10I | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.509); catalogued as rs777557673, COSV53309155; called by muse, mutect2, varscan2
- ADAMTS15 | c.168G>C p.Q56H | Missense Mutation (SNP) | VAF 138/309 reads (45%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.897); called by muse, varscan2
- ADAMTS9 | c.2650C>A p.H884N | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATM | c.7309T>A p.Y2437N | Missense Mutation (SNP) | VAF 4/97 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2
- COL20A1 | c.1799G>C p.G600A | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DDX56 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 90/324 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM104A | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); called by muse, mutect2
- FAU | c.356T>C p.V119A | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FGA | c.706A>C p.N236H | Missense Mutation (SNP) | VAF 13/210 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- HSPA8 | c.411+2T>C p.X137_splice | Splice Site (SNP) | VAF 73/297 reads (25%) | called by muse, mutect2, varscan2
- HUWE1 | c.2261+2T>G p.X754_splice | Splice Site (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- ITK | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 31/183 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0); called by mutect2, varscan2
- KDR | c.3644A>G p.D1215G | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.999); called by muse, varscan2
- LILRB5 | c.8T>A p.L3H | Missense Mutation (SNP) | VAF 86/293 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- LNX2 | c.2020C>T p.Q674* | Nonsense Mutation (SNP) | VAF 72/254 reads (28%) | called by muse, mutect2, varscan2
- MGAT4C | c.1176T>G p.I392M | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- NAA40 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- NPC1 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDHA2 | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PTPN14 | c.2532G>C p.E844D | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- SAMHD1 | c.1459G>A p.V487I | Missense Mutation (SNP) | VAF 46/431 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D12 | c.1450G>A p.G484R | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMEM106B | c.462C>A p.N154K | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- TMPRSS9 | c.2792G>A p.R931H (on ENST00000648592; = p.R897H on NM_182973.2) | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- UNC5D | c.239C>G p.A80G | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ACSS1 | c.1590C>T p.F530= | Silent (SNP) | VAF 8/155 reads (5%) | catalogued as COSV60223539; called by muse, mutect2
- CPT1C | c.1764G>A p.S588= | Silent (SNP) | VAF 60/134 reads (45%) | catalogued as rs780554652; called by muse, mutect2, varscan2
- DNAJC28 | c.6T>C p.N2= | Silent (SNP) | VAF 18/466 reads (4%) | called by muse, mutect2
- EIF4G2 | c.2301A>G p.G767= | Silent (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- FAIM | c.189G>A p.A63= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs372907141; called by muse, mutect2, varscan2
- FGL1 | c.669G>T p.V223= | Silent (SNP) | VAF 33/234 reads (14%) | catalogued as rs762934688; called by muse, mutect2, varscan2
- ILDR1 | c.84C>G p.V28= | Silent (SNP) | VAF 15/202 reads (7%) | called by muse, mutect2
- OPHN1 | c.2229G>A p.R743= | Silent (SNP) | VAF 33/106 reads (31%) | catalogued as rs1468837677, COSV100830339; called by muse, mutect2, varscan2
- POGK | c.1116G>A p.V372= | Silent (SNP) | VAF 37/213 reads (17%) | catalogued as rs1392112727; called by muse, mutect2, varscan2
- SERPINA5 | c.111T>C p.G37= | Silent (SNP) | VAF 140/332 reads (42%) | called by muse, mutect2, varscan2
- STC2 | c.177C>T p.N59= | Silent (SNP) | VAF 162/616 reads (26%) | catalogued as rs201103640, COSV54182900; called by muse, varscan2
- TRBV28 | c.54C>T p.L18= | Silent (SNP) | VAF 18/283 reads (6%) | catalogued as rs758267657; called by muse, mutect2
- ABCC9 | chr12:21800231 G>T | 3'Flank (SNP) | VAF 13/61 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP28 | c.*2783G>T | 3'UTR (SNP) | VAF 22/111 reads (20%) | called by muse, mutect2, varscan2
- ASRGL1 | c.*1097A>T | 3'UTR (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- C1QTNF6 | c.*1840C>T | 3'UTR (SNP) | VAF 36/217 reads (17%) | called by muse, mutect2, varscan2
- C1orf159 | c.73-15G>A | Intron (SNP) | VAF 75/153 reads (49%) | catalogued as rs777949795; called by muse, mutect2, varscan2
- C20orf96 | c.21-50C>T | Intron (SNP) | VAF 243/535 reads (45%) | called by muse, mutect2, varscan2
- CASC3 | c.232-96T>C | Intron (SNP) | VAF 96/260 reads (37%) | called by muse, mutect2, varscan2
- COA1 | c.-38-738T>C | Intron (SNP) | VAF 34/79 reads (43%) | called by muse, mutect2, varscan2
- DPYSL5 | c.*2427G>A | 3'UTR (SNP) | VAF 79/186 reads (42%) | called by muse, mutect2, varscan2
- EPHA7 | c.832+527C>G | Intron (SNP) | VAF 16/76 reads (21%) | called by muse, mutect2, varscan2
- FAXDC2 | c.*821G>C | 3'UTR (SNP) | VAF 35/129 reads (27%) | called by muse, mutect2, varscan2
- FBN2 | c.952+4386T>C | Intron (SNP) | VAF 27/66 reads (41%) | called by muse, mutect2, varscan2
- FGL2 | c.*802G>A | 3'UTR (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- FMN1 | c.*6727G>A | 3'UTR (SNP) | VAF 13/33 reads (39%) | called by muse, mutect2, varscan2
- FP565260.6 | c.*2273A>G | 3'UTR (SNP) | VAF 5/57 reads (9%) | catalogued as rs1466789100; called by muse, mutect2
- H6PD | c.*6104G>A | 3'UTR (SNP) | VAF 24/48 reads (50%) | catalogued as rs986903983; called by muse, mutect2
- JAGN1 | chr3:9890584 C>A | 5'Flank (SNP) | VAF 25/58 reads (43%) | called by muse, mutect2, varscan2
- LIFR | c.*2063T>G | 3'UTR (SNP) | VAF 46/117 reads (39%) | called by muse, mutect2, varscan2
- LTB | c.163-135C>T | Intron (SNP) | VAF 158/345 reads (46%) | called by muse, mutect2, varscan2
- MTR | c.*118T>C | 3'UTR (SNP) | VAF 82/358 reads (23%) | called by muse, mutect2
- NEK9 | c.*2396G>C | 3'UTR (SNP) | VAF 5/100 reads (5%) | called by muse, mutect2
- NEU4 | c.457+190G>A | Intron (SNP) | VAF 7/56 reads (13%) | catalogued as rs1459987125, COSV57990713; called by muse, varscan2
- PCBP2P2 | n.935C>T | RNA (SNP) | VAF 5/48 reads (10%) | catalogued as rs906225866; called by muse, mutect2, varscan2
- PDGFA | chr7:498151 C>A | 3'Flank (SNP) | VAF 21/218 reads (10%) | called by muse, mutect2
- PTPRT | c.*6268C>T | 3'UTR (SNP) | VAF 12/298 reads (4%) | called by muse, mutect2
- RNF217 | c.*3360T>A | 3'UTR (SNP) | VAF 20/80 reads (25%) | called by muse, mutect2, varscan2
- RPL32 | c.-91G>A | 5'UTR (SNP) | VAF 10/204 reads (5%) | called by muse, mutect2
- SEC61A2 | chr10:12169362 C>T | 3'Flank (SNP) | VAF 79/563 reads (14%) | catalogued as rs1052473312, COSV53652140; called by muse, mutect2, varscan2
- SEMA5B | c.*480G>A | 3'UTR (SNP) | VAF 24/95 reads (25%) | called by muse, mutect2, varscan2
- SERPINI2 | c.-11+196C>T | Intron (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- SGCB | c.*1208del | 3'UTR (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel, varscan2
- SI | c.*333A>T | 3'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, mutect2
- SLITRK2 | chrX:145828317 A>G | 3'Flank (SNP) | VAF 30/32 reads (94%) | called by muse, mutect2, varscan2
- SRGAP3 | c.1324-1937G>A | Intron (SNP) | VAF 21/156 reads (13%) | catalogued as rs1047185170; called by muse, mutect2, varscan2
- SRSF12 | c.*2484T>C | 3'UTR (SNP) | VAF 34/103 reads (33%) | called by muse, mutect2, varscan2
- SSR1 | c.*2635T>C | 3'UTR (SNP) | VAF 35/92 reads (38%) | called by muse, mutect2, varscan2
- SUPT16H | c.*529G>C | 3'UTR (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- TRBV5-4 | c.-9C>A | 5'UTR (SNP) | VAF 12/56 reads (21%) | catalogued as rs766541865; called by muse, varscan2
- TRIM36 | c.63+2793G>T | Intron (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2, varscan2
- TXNDC16 | c.-46A>C | 5'UTR (SNP) | VAF 111/358 reads (31%) | called by muse, mutect2, varscan2
- ZBED2 | c.*275G>C | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, mutect2
- ZNF44 | c.*777C>A | 3'UTR (SNP) | VAF 80/161 reads (50%) | called by muse, mutect2, varscan2
